Somatic mutation profile of tumor specimen TCGA-DJ-A13L-01A (aliquot TCGA-DJ-A13L-01A-11D-A21Z-08) from TCGA case TCGA-DJ-A13L, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 85.9 years (31,388 days).
Specimen TCGA-DJ-A13L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4e34891-575d-41da-87d8-507decb2e5fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13L-10A (Blood Derived Normal), aliquot TCGA-DJ-A13L-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3b1e637-2e41-42cc-b601-63b14add6808

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 25, Silent 7, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANKEF1 | c.667C>G p.H223D | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101001064; called by muse, mutect2
- CTSS | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs140031053; called by muse, mutect2
- CUL9 | c.4792C>T p.Q1598* | Nonsense Mutation (SNP) | VAF 20/187 reads (11%) | catalogued as COSV52733145; called by muse, mutect2
- EEF1A2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53204763; called by muse, mutect2, varscan2
- FBN1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as CM020134, COSV100356289; called by muse, mutect2
- HSD3B7 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746072197, COSV99288364; called by muse, mutect2, varscan2
- OR4C11 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56352669; called by muse, mutect2, varscan2
- PRAG1 | c.2510C>T p.S837F | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1365636144; called by muse, mutect2, varscan2
- PRKDC | c.4643G>T p.G1548V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV58057160; called by muse, mutect2
- PRSS48 | c.317C>A p.P106H | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1256053069, COSV101490184; called by muse, mutect2
- SBF1 | c.4140C>G p.F1380L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs760115907, COSV100817415, COSV62370795; called by mutect2, varscan2
- SPTY2D1 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100311839; called by muse, mutect2
- TBX3 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 7/83 reads (8%) | catalogued as COSV57470251; called by muse, mutect2
- TYRP1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs886063413, COSV104429659, COSV66357914, COSV66358419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANGPT2 | c.777_780del p.T260* | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- DUSP5 | c.409C>G p.P137A | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GFRA3 | c.435G>C p.W145C | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HYPK | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF21A | c.3656C>T p.S1219F (on ENST00000361418 / NM_001378440.1; = p.S1206F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.466); called by muse, mutect2
- OR7A5 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTGR2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RYR1 | c.3206A>T p.D1069V | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SECISBP2L | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2
- STAM2 | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2
- TBC1D9 | c.3353C>G p.A1118G | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIGD7 | c.1028dup p.W344Mfs*5 | Frame Shift Ins (INS) | VAF 8/80 reads (10%) | called by mutect2, pindel
- WDR45B | c.369C>G p.F123L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2
- DOLK | c.21T>C p.S7= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1056131501; called by muse, mutect2, varscan2
- DVL3 | c.639G>A p.L213= | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- FERMT1 | c.1281C>T p.P427= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as COSV54094055; called by muse, mutect2, varscan2
- POLE | c.4252C>T p.L1418= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100268051; called by muse, mutect2
- PRKDC | c.4644C>T p.G1548= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2
- STK31 | c.621A>T p.G207= | Silent (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- WDR76 | c.330A>G p.Q110= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as rs760925288; called by muse, mutect2, varscan2
